Somatic mutation profile of tumor specimen ALCH-ADU3-TTP1-A (aliquot ALCH-ADU3-TTP1-A-10-0-D-A532-36) from ALCHEMIST case ALCH-ADU3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 54.2 years (19,804 days).
Specimen ALCH-ADU3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c15aec0-16c9-420b-a5a9-310bd35cb136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADU3-NB1-A (Blood Derived Normal), aliquot ALCH-ADU3-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57dc757e-f359-4667-b306-3cc468b68a79

The open-access MAF lists 346 somatic variants for this specimen: 232 protein-altering or splice-affecting, 63 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 63, Intron 20, Nonsense Mutation 13, Frame Shift Del 10, 3'UTR 9, 5'UTR 9, RNA 5, 5'Flank 4, 3'Flank 4, Splice Region 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 257/683 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2512A>G p.I838V | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs780819239, COSV60686927; called by muse, mutect2, varscan2
- ABCC8 | c.4253G>T p.R1418L | Missense Mutation (SNP) | VAF 201/743 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446306735, CM043738, CM144517, COSV100217047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD3 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 323/557 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100830941; called by muse, mutect2, varscan2
- ACO2 | c.260del p.S87Cfs*43 | Frame Shift Del (DEL) | VAF 112/560 reads (20%) | catalogued as COSV53443452; called by mutect2, pindel*, varscan2
- ADGRE1 | c.1050T>G p.C350W | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267605755; called by muse, mutect2, varscan2
- ADGRL4 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV99056123; called by muse, mutect2, varscan2
- ALPK2 | c.5338A>G p.K1780E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1012296926; called by mutect2, varscan2
- ANKRD11 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 222/736 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1318137276, COSV56363032; called by muse, mutect2, varscan2
- ANO4 | c.376A>G p.R126G (on ENST00000392977 / NM_001286615.2; = p.R91G on NM_178826.4) | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs1381146340; called by muse, varscan2
- ARHGEF26 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 114/357 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV62850003; called by muse, mutect2, varscan2
- BDH1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.154); catalogued as rs780658065, COSV64018053; called by muse, mutect2, varscan2
- BIRC6 | c.8815G>T p.E2939* | Nonsense Mutation (SNP) | VAF 84/325 reads (26%) | catalogued as COSV70205608; called by muse, mutect2, varscan2
- BTNL8 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs764166999; called by muse, mutect2, varscan2
- C6orf163 | c.778del p.E260Sfs*5 | Frame Shift Del (DEL) | VAF 98/345 reads (28%) | catalogued as COSV65825456; called by mutect2, pindel, varscan2
- CACNB2 | c.484C>T p.R162* (on ENST00000324631 / NM_201596.3; = p.R107* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 137/555 reads (25%) | catalogued as rs1257625518, COSV56640971; called by muse, mutect2, varscan2
- CALCOCO1 | c.1886A>G p.Y629C | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs748122359; called by muse, mutect2
- CALCR | c.699G>C p.V233= (on ENST00000649521 / NM_001164737.2; = p.V217= on NM_001742.4) | Splice Region (SNP) | VAF 39/125 reads (31%) | catalogued as COSV64012117; called by muse, mutect2, varscan2
- CCDC191 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 126/1186 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55562008; called by muse, mutect2, varscan2
- CDH18 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV56908537, COSV56961245; called by muse, mutect2, varscan2
- CDK15 | c.389C>G p.A130G (on ENST00000652192 / NM_001366386.2; = p.A79G on NM_139158.2) | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99643479; called by muse, mutect2, varscan2
- CDK8 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67423403; called by muse, mutect2, varscan2
- CERT1 | c.2104C>G p.L702V (on ENST00000405807 / NM_001130105.1; = p.L574V on NM_005713.3) | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV54665177; called by muse, varscan2
- COL19A1 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs751493605; called by muse, mutect2, varscan2
- CTSO | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.041); catalogued as rs902128830; called by muse, mutect2, varscan2
- DCDC1 | c.2750C>A p.P917Q (on ENST00000597505 / NM_001367979.1; = p.P24Q on NM_020869.3) | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60315112; called by muse, mutect2, varscan2
- DCHS1 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 160/711 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as rs200122562, COSV100197750; called by muse, mutect2, varscan2
- DEFB129 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs909337336; called by muse, mutect2, varscan2
- DNAH10 | c.10078G>A p.A3360T (on ENST00000409039; = p.A3299T on NM_207437.3) | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs757536034; called by muse, mutect2
- DZIP3 | c.1699G>C p.V567L | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV64313707; called by muse, mutect2, varscan2
- EPHA3 | c.1481T>G p.V494G | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60725441; called by muse, mutect2, varscan2
- FAM135A | c.2670C>G p.I890M (on ENST00000370479 / NM_001351599.1; = p.I677M on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.352); catalogued as rs1401672680; called by muse, mutect2, varscan2
- FAM135B | c.2611C>G p.P871A | Missense Mutation (SNP) | VAF 106/748 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs771228609, COSV52709212, COSV99429035; called by muse, mutect2, varscan2
- FCSK | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 24/346 reads (7%) | catalogued as COSV99851101; called by muse, mutect2
- FLG | c.4649C>A p.S1550* | Nonsense Mutation (SNP) | VAF 76/882 reads (9%) | catalogued as rs200294818, COSV64242625; called by muse, mutect2
- FNDC1 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51950403; called by muse, mutect2, varscan2
- FOXP2 | c.1765A>G p.T589A | Missense Mutation (SNP) | VAF 78/461 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV100647385; called by muse, mutect2, varscan2
- FSHR | c.1854C>A p.N618K | Missense Mutation (SNP) | VAF 136/480 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58620249; called by muse, mutect2, varscan2
- GAS6 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59856728; called by muse, mutect2, varscan2
- GGN | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 187/743 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as rs770034069; called by muse, mutect2, varscan2
- H2AC15 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 198/515 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57586363; called by muse, mutect2, varscan2
- HOXB8 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1567981413; called by muse, mutect2, varscan2
- IFNAR2 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs150933837; called by muse, mutect2, varscan2
- ITFG1 | c.528T>A p.N176K | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.037); catalogued as rs766116931; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1302C>A p.S434R (on ENST00000439118 / NM_001008949.3; = p.S442R on NM_178495.6) | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs537953486; called by muse, mutect2, varscan2
- KCNQ3 | c.1566C>A p.V522= | Splice Region (SNP) | VAF 21/88 reads (24%) | catalogued as COSV66480558; called by muse, varscan2
- KEAP1 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV50262614, COSV50271993; called by muse, mutect2, varscan2
- KIDINS220 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1158181513; called by muse, mutect2, varscan2
- KIF24 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs772524878; called by muse, mutect2, varscan2
- KRT83 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 179/670 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV53342581; called by muse, mutect2, varscan2
- LMAN2L | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1376093023; called by muse, mutect2, varscan2
- LRP1B | c.12486G>C p.L4162F | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101253386, COSV101253676; called by muse, varscan2
- LYST | c.4013A>G p.Q1338R | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.584); catalogued as COSV101088284; called by muse, mutect2, varscan2
- MAP3K1 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 163/795 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1305030339, COSV68121625, COSV68124440; called by muse, mutect2, varscan2
- MCIDAS | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 125/407 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs767671978; called by muse, mutect2, varscan2
- MYH13 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs781028573, COSV99355691; called by muse, mutect2, varscan2
- NCOR2 | c.7522G>A p.E2508K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216174003; called by muse, mutect2, varscan2
- NEK4 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV51780755; called by muse, mutect2, varscan2
- NMD3 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 145/356 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs999931423; called by muse, mutect2, varscan2
- NRXN1 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV68005892; called by muse, mutect2, varscan2
- OR8H3 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV57908076; called by muse, mutect2, varscan2
- OTP | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.9); catalogued as COSV100119909; called by muse, mutect2, varscan2
- PCDHB6 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs372785699; called by muse, mutect2
- PCDHGB1 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs1181723037, COSV53919361; called by muse, mutect2, varscan2
- PDE6B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 142/556 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as CM1410768, COSV55331111; called by muse, varscan2
- PKD2L1 | c.1248del p.K417Sfs*25 | Frame Shift Del (DEL) | VAF 65/276 reads (24%) | catalogued as COSV58395388; called by mutect2, pindel, varscan2
- PRELP | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 379/605 reads (63%) | SIFT tolerated (0.98); PolyPhen benign (0.013); catalogued as rs574411918, COSV100557800; called by muse, mutect2, varscan2
- PRKACB | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs769500443; called by muse, mutect2, varscan2
- PROCA1 | c.430C>T p.R144W (on ENST00000439862 / NM_001366301.1; = p.R116W on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372096791; called by muse, mutect2, varscan2
- REG1B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 97/451 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.19); catalogued as COSV59305183; called by muse, mutect2, varscan2
- REG3A | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV59412199, COSV59412447; called by muse, mutect2
- SCP2 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65261335; called by muse, varscan2
- SVEP1 | c.8473G>A p.E2825K | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.426); catalogued as COSV52843997; called by muse, mutect2, varscan2
- SYNE1 | c.2066G>T p.R689L (on ENST00000367255 / NM_182961.4; = p.R696L on NM_033071.3) | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55019241; called by muse, mutect2, varscan2
- TEX47 | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs1410217147; called by muse, mutect2, varscan2
- TEX51 | c.560G>A p.R187K (on ENST00000643416; = p.G162R on NM_001322244.2) | Missense Mutation (SNP) | VAF 88/387 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs752180864; called by muse, mutect2, varscan2
- TNFRSF11B | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52069993; called by muse, mutect2, varscan2
- TP53 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 259/687 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52661621, COSV52849794, COSV52892313, COSV53037823; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs375272521; called by muse, mutect2, varscan2
- TTN | c.10494G>C p.K3498N (on ENST00000591111; = p.K3452N on NM_003319.4) | Missense Mutation (SNP) | VAF 138/572 reads (24%) | catalogued as COSV60004614; called by muse, mutect2, varscan2
- VSX1 | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 152/566 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1236033052; called by muse, mutect2, varscan2
- WDR19 | c.2972A>G p.N991S | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs763190830; called by muse, mutect2, varscan2
- ZBTB16 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs749320934, COSV60092952, COSV60097758; called by muse, mutect2, varscan2
- ZNF362 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV65031637; called by muse, mutect2, varscan2
- ZNF534 | c.1634G>A p.R545H (on ENST00000332323 / NM_001143939.3; = p.R532H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as rs749239167, COSV56517458; called by muse, mutect2, varscan2
- ZNF730 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs911233103, COSV74168222; called by muse, mutect2, varscan2
- ZNF735 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1174798557; called by muse, mutect2, varscan2
- ZNF821 | c.965G>C p.R322P (on ENST00000425432 / NM_001376297.1; = p.R280P on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/494 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57987916; called by muse, mutect2, varscan2
- ZRANB3 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs752457551; called by muse, varscan2
- ABHD12 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); called by muse, varscan2
- ADGRB3 | c.1908C>G p.I636M | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AMPH | c.1370G>C p.R457P | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6475A>G p.I2159V | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP1 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CAMTA1 | c.2855A>T p.Y952F | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CATSPERE | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 165/288 reads (57%) | called by muse, mutect2, varscan2
- CC2D2B | c.741T>G p.N247K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2
- CCDC175 | c.1354T>C p.C452R | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); called by muse, varscan2
- CCDC73 | c.2695C>A p.P899T | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CD1B | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 282/526 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CDH19 | c.661T>C p.W221R | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDHR2 | c.2041G>C p.V681L | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CEP120 | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 136/557 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP131 | c.1606T>G p.L536V (on ENST00000269392 / NM_001319228.2; = p.L533V on NM_014984.4) | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD7 | c.4627G>C p.D1543H | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CHRM3 | c.345_348del p.I116Sfs*6 | Frame Shift Del (DEL) | VAF 68/421 reads (16%) | called by mutect2, pindel, varscan2
- CLASRP | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT tolerated (0.07); called by muse, varscan2
- COL17A1 | c.3772G>C p.D1258H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COL22A1 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 104/379 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL6A6 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 109/198 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPSF3 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CPXCR1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- CRMP1 | c.1409del p.P470Rfs*77 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | called by mutect2, varscan2
- CRYL1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CTNND2 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 178/625 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYB5R4 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYLC1 | c.668A>C p.D223A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DECR1 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1B | c.983G>T p.R328M | Missense Mutation (SNP) | VAF 152/267 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DMGDH | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 136/519 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- DNHD1 | c.4587G>T p.E1529D | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK10 | c.5084C>G p.T1695S | Missense Mutation (SNP) | VAF 158/675 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- DUS1L | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 115/399 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EEF1AKMT1 | c.555G>C p.M185I | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF2B5 | c.1912C>T p.P638S (on ENST00000647909; = p.P630S on NM_003907.3) | Missense Mutation (SNP) | VAF 351/953 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ENTPD2 | c.1275C>A p.F425L (on ENST00000355097 / NM_203468.3; = p.F402L on NM_001246.4) | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EPDR1 | c.509A>T p.K170M | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHB3 | c.1056A>C p.E352D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FCGBP | c.2581T>A p.F861I | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FLRT3 | c.1223G>T p.R408I | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FNIP2 | c.655+6A>G | Splice Region (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- FOLH1 | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRG1 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG2 | c.828G>T p.R276S (on ENST00000361925 / NM_001375343.1; = p.R236S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/604 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- GALNT13 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GALNT14 | c.478_492del p.K160_K164del | In Frame Del (DEL) | VAF 61/440 reads (14%) | called by mutect2, pindel, varscan2
- GBP5 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GFRA4 | c.872C>G p.P291R (on ENST00000319242 / NM_145762.3; = p.P261R on NM_022139.4) | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- GNPDA2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- GOLGB1 | c.4543C>G p.R1515G | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPR149 | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR6 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR61 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 97/310 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GRIA4 | c.1348T>G p.L450V | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GRIN2B | c.2974del p.H992Ifs*64 | Frame Shift Del (DEL) | VAF 162/671 reads (24%) | called by mutect2, pindel, varscan2
- GTF2H2 | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 70/555 reads (13%) | called by muse, mutect2, varscan2
- HHLA1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, varscan2
- IGDCC3 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 210/379 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- IGF1 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1-8 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-42 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITM2A | c.703+2T>A p.X235_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- KANSL3 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KCNE4 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 279/948 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIFC2 | c.1849C>G p.P617A | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIRREL1 | c.1680C>A p.S560R | Missense Mutation (SNP) | VAF 76/449 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KIRREL3 | c.968C>A p.T323N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KMT2D | c.11858A>G p.Q3953R | Missense Mutation (SNP) | VAF 188/749 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, varscan2
- LAMA1 | c.8941C>T p.Q2981* | Nonsense Mutation (SNP) | VAF 63/823 reads (8%) | called by muse, mutect2
- LILRA4 | c.1424dup p.R476Kfs*28 | Frame Shift Ins (INS) | VAF 87/366 reads (24%) | called by mutect2, varscan2
- LRP1B | c.12387T>A p.Y4129* | Nonsense Mutation (SNP) | VAF 72/246 reads (29%) | called by muse, varscan2
- LRP3 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MARCHF10 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 193/616 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIB1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYC | c.194G>T p.R65L (on ENST00000377970; = p.R80L on NM_002467.6) | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH15 | c.2753A>C p.E918A | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2
- NBEAL1 | c.6581C>T p.S2194L | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NLRP9 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 144/536 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NRBF2 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR5D13 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- P3H1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 225/817 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PAG1 | c.83T>C p.F28S | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2
- PCSK2 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PDZRN4 | c.2698T>G p.Y900D (on ENST00000402685 / NM_001164595.2; = p.Y642D on NM_013377.4) | Missense Mutation (SNP) | VAF 89/420 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIWIL2 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKD1L1 | c.7943C>G p.P2648R | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PLCL2 | c.974A>T p.E325V (on ENST00000615277 / NM_001144382.2; = p.E199V on NM_015184.5) | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PPP1R2 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PPP1R2B | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, varscan2
- PPP1R3G | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 145/580 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PRKD1 | c.1164C>A p.D388E | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2
- PRSS56 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- RCBTB1 | c.1295_1296del p.T432Sfs*20 | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | called by pindel, varscan2
- RGS1 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- RIMS1 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPRY1 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RTN4 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCGB2A2 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 126/493 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SCN10A | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 110/337 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDCCAG8 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 147/816 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SERPINA11 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIRT1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.081); called by muse, mutect2
- SLC24A2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.017); called by muse, varscan2
- SLC9A4 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.1422T>A p.C474* | Nonsense Mutation (SNP) | VAF 77/396 reads (19%) | called by muse, mutect2, varscan2
- SNX25 | c.1044A>C p.E348D | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SP140 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPOCD1 | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SPRYD7 | c.424_425del p.Y142Lfs*24 | Frame Shift Del (DEL) | VAF 70/222 reads (32%) | called by pindel, varscan2
- ST6GAL2 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 90/350 reads (26%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STPG2 | c.1322T>A p.I441K | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- STYX | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SUGP2 | c.2396G>A p.G799E | Missense Mutation (SNP) | VAF 126/534 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.8818G>C p.E2940Q | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SYNE1 | c.14384A>T p.K4795M (on ENST00000367255 / NM_182961.4; = p.K4724M on NM_033071.3) | Missense Mutation (SNP) | VAF 176/637 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TANC1 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TBC1D4 | c.3646C>T p.L1216F | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECRL | c.300C>A p.Y100* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- TESK2 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TEX15 | c.655C>A p.P219T (on ENST00000638951; = p.P215T on NM_001350162.2) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); called by muse, varscan2
- TGFBI | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM160 | c.65_83del p.L22Pfs*103 | Frame Shift Del (DEL) | VAF 24/153 reads (16%) | called by mutect2, pindel, varscan2
- TMPRSS11A | c.1144_1145del p.D382Yfs*13 | Frame Shift Del (DEL) | VAF 57/259 reads (22%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.1874G>C p.G625A | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TPO | c.2644C>G p.L882V | Missense Mutation (SNP) | VAF 298/1171 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TTL | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 70/258 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 224/828 reads (27%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBB8 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 154/684 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- UNC80 | c.6959T>A p.L2320Q | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UNC93A | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, varscan2
- USP48 | c.516G>C p.L172F | Missense Mutation (SNP) | VAF 98/407 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- USP9X | c.5758T>C p.C1920R | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 101/353 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- XIRP2 | c.6700G>T p.A2234S (on ENST00000628543; = p.A2409S on NM_152381.6) | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZEB1 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN2 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 135/554 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF208 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF461 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZNF462 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 293/802 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF727 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF761 | c.2166G>T p.E722D | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AGXT2 | c.225T>C p.S75= | Silent (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2, varscan2
- ANK3 | c.2559A>G p.K853= | Silent (SNP) | VAF 74/331 reads (22%) | called by muse, mutect2, varscan2
- ANKRD11 | c.1506C>G p.L502= | Silent (SNP) | VAF 180/530 reads (34%) | called by muse, mutect2, varscan2
- ARRDC2 | c.204C>T p.S68= | Silent (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- ATP2B3 | c.294C>T p.F98= | Silent (SNP) | VAF 140/381 reads (37%) | called by muse, mutect2, varscan2
- CBX2 | c.735C>T p.P245= | Silent (SNP) | VAF 75/252 reads (30%) | catalogued as rs200705902; called by muse, mutect2, varscan2
- CDK1 | c.417A>G p.K139= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- CDK15 | c.984C>A p.V328= (on ENST00000652192 / NM_001366386.2; = p.V277= on NM_139158.2) | Silent (SNP) | VAF 77/355 reads (22%) | catalogued as rs762160050; called by muse, mutect2, varscan2
- COCH | c.52C>T p.L18= | Silent (SNP) | VAF 140/464 reads (30%) | called by muse, mutect2, varscan2
- CTCF | c.222G>A p.K74= | Silent (SNP) | VAF 94/254 reads (37%) | called by muse, mutect2, varscan2
- DHX9 | c.264G>A p.P88= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs762027336; called by muse, mutect2, varscan2
- DPY19L2 | c.1488A>G p.L496= | Silent (SNP) | VAF 51/195 reads (26%) | catalogued as rs768338736; called by muse, mutect2, varscan2
- DRD5 | c.90G>T p.S30= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV58578478; called by muse, varscan2
- DSG4 | c.3048C>A p.T1016= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV57392755; called by muse, mutect2
- FAM135B | c.3141G>A p.V1047= | Silent (SNP) | VAF 93/219 reads (42%) | called by muse, mutect2, varscan2
- FBXO7 | c.777T>C p.I259= | Silent (SNP) | VAF 157/670 reads (23%) | called by muse, mutect2, varscan2
- FGF14 | c.9G>T p.A3= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, varscan2
- HDGFL1 | c.117G>A p.Q39= | Silent (SNP) | VAF 237/628 reads (38%) | called by muse, mutect2, varscan2
- HIVEP2 | c.624C>T p.I208= | Silent (SNP) | VAF 68/260 reads (26%) | called by muse, mutect2, varscan2
- ITGA11 | c.2172C>G p.S724= | Silent (SNP) | VAF 153/294 reads (52%) | catalogued as COSV100242172; called by muse, mutect2, varscan2
- KATNA1 | c.771C>T p.L257= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as rs1156425942; called by muse, mutect2, varscan2
- KCNK15 | c.468G>A p.T156= | Silent (SNP) | VAF 89/366 reads (24%) | catalogued as rs1379059322; called by muse, mutect2, varscan2
- KCNK6 | c.681C>T p.G227= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- KLHL34 | c.1269G>C p.V423= | Silent (SNP) | VAF 128/214 reads (60%) | called by muse, mutect2, varscan2
- LYST | c.4011C>T p.C1337= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV67707050; called by muse, mutect2, varscan2
- MACC1 | c.432G>T p.L144= | Silent (SNP) | VAF 60/295 reads (20%) | called by muse, mutect2, varscan2
- MED13L | c.4191G>A p.S1397= | Silent (SNP) | VAF 160/862 reads (19%) | catalogued as rs373550838; called by muse, mutect2, varscan2
- MFN1 | c.1449A>G p.L483= | Silent (SNP) | VAF 114/180 reads (63%) | called by muse, mutect2, varscan2
- MROH5 | c.2553C>T p.A851= | Silent (SNP) | VAF 87/159 reads (55%) | catalogued as rs1475413148; called by muse, mutect2, varscan2
- MSANTD1 | c.357G>A p.P119= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs368238729; called by muse, mutect2, varscan2
- NAT8L | c.819C>T p.Y273= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs749841631; called by muse, mutect2, varscan2
- NAV3 | c.2235C>A p.G745= | Silent (SNP) | VAF 63/263 reads (24%) | catalogued as COSV99894684; called by muse, mutect2, varscan2
- NPHP3 | c.3885A>G p.T1295= | Silent (SNP) | VAF 123/597 reads (21%) | called by muse, mutect2, varscan2
- NUMBL | c.243G>A p.P81= | Silent (SNP) | VAF 47/544 reads (9%) | catalogued as rs1459563650; called by muse, mutect2
- OR51B2 | c.906C>T p.I302= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV100173230; called by muse, mutect2, varscan2
- OR5K2 | c.189G>A p.L63= | Silent (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- PCDH9 | c.1038C>A p.I346= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV60576844; called by muse, mutect2, varscan2
- PGBD1 | c.1419T>A p.P473= | Silent (SNP) | VAF 104/285 reads (36%) | called by muse, mutect2, varscan2
- PIK3CG | c.3123G>A p.Q1041= | Silent (SNP) | VAF 69/277 reads (25%) | called by muse, mutect2, varscan2
- PPP1R9A | c.1002C>A p.S334= | Silent (SNP) | VAF 85/493 reads (17%) | called by muse, mutect2, varscan2
- PRLR | c.663G>A p.A221= | Silent (SNP) | VAF 105/319 reads (33%) | catalogued as rs780563899, COSV51501614; called by muse, mutect2, varscan2
- PRR5 | c.672C>T p.F224= (on ENST00000336985 / NM_181333.4; = p.F215= on NM_015366.4) | Silent (SNP) | VAF 55/173 reads (32%) | called by muse, mutect2, varscan2
- RETSAT | c.258A>G p.L86= | Silent (SNP) | VAF 101/409 reads (25%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.621G>A p.P207= | Silent (SNP) | VAF 109/389 reads (28%) | catalogued as rs777013826, COSV99549322; called by muse, mutect2, varscan2
- RPL18 | c.15C>T p.I5= | Silent (SNP) | VAF 38/260 reads (15%) | called by muse, mutect2, varscan2
- SESTD1 | c.327G>T p.T109= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as rs765983135, COSV70568218; called by muse, mutect2, varscan2
- SLC35B4 | c.174A>G p.P58= | Silent (SNP) | VAF 65/215 reads (30%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1698C>T p.V566= (on ENST00000517878 / NM_001286646.2; = p.V515= on NM_001080431.2) | Silent (SNP) | VAF 145/897 reads (16%) | called by muse, mutect2, varscan2
- SLC7A2 | c.1236C>T p.D412= (on ENST00000494857 / NM_001370338.1; = p.D451= on NM_003046.6) | Silent (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- SRRM2 | c.6792A>T p.A2264= | Silent (SNP) | VAF 55/208 reads (26%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.1080C>T p.F360= | Silent (SNP) | VAF 122/1182 reads (10%) | catalogued as rs114276943; called by muse, mutect2
- SVEP1 | c.8079G>A p.G2693= | Silent (SNP) | VAF 124/289 reads (43%) | catalogued as rs959056119, COSV52844053; called by muse, varscan2
- SYNE1 | c.15627A>T p.A5209= (on ENST00000367255 / NM_182961.4; = p.A5138= on NM_033071.3) | Silent (SNP) | VAF 146/557 reads (26%) | called by muse, mutect2, varscan2
- TAF6 | c.84C>T p.I28= | Silent (SNP) | VAF 126/389 reads (32%) | catalogued as rs957139683, COSV59840383; called by muse, mutect2, varscan2
- TBK1 | c.1932A>G p.V644= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2
- TBX10 | c.27C>A p.L9= | Silent (SNP) | VAF 129/524 reads (25%) | called by muse, mutect2, varscan2
- TMEM221 | c.303G>A p.R101= | Silent (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- TRPS1 | c.2850A>G p.R950= (on ENST00000220888 / NM_001330599.2; = p.R963= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV55230282; called by muse, varscan2
- UTRN | c.7488G>A p.Q2496= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- ZNF362 | c.1242G>T p.P414= | Silent (SNP) | VAF 76/326 reads (23%) | catalogued as rs138022975; called by muse, mutect2, varscan2
- ZNF415 | c.24C>T p.F8= | Silent (SNP) | VAF 45/210 reads (21%) | catalogued as COSV54704069; called by muse, mutect2, varscan2
- ZNF496 | c.1407G>T p.G469= | Silent (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- ZNF750 | c.189C>A p.P63= | Silent (SNP) | VAF 484/1790 reads (27%) | called by muse, mutect2, varscan2
- AC011455.2 | c.*35G>C | 3'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- AC022415.2 | c.*1299G>A | 3'UTR (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- API5 | c.*20C>T | 3'UTR (SNP) | VAF 33/141 reads (23%) | called by muse, varscan2
- C1orf122 | chr1:37807779 G>T | 5'Flank (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- CCS | c.-77A>T | 5'UTR (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- COL5A1 | c.3528+29G>T | Intron (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588960 G>T | 5'Flank (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- ECPAS | chr9:111484376 G>T | 5'Flank (SNP) | VAF 83/392 reads (21%) | called by muse, mutect2, varscan2
- ENO2 | c.310+56G>A | Intron (SNP) | VAF 48/137 reads (35%) | called by muse, mutect2, varscan2
- EPB42 | c.*35T>C | 3'UTR (SNP) | VAF 202/357 reads (57%) | catalogued as rs1197490062; called by muse, mutect2, varscan2
- EYA4 | c.1299+33C>A | Intron (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- FAM183BP | n.687T>G | RNA (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- FAM227B | c.1013-51314C>T | Intron (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- FOXJ3 | c.444+96G>A | Intron (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- GVINP1 | n.2118T>A | RNA (SNP) | VAF 50/223 reads (22%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1520C>G | RNA (SNP) | VAF 214/566 reads (38%) | called by muse, varscan2
- HTR3A | c.*114C>A | 3'UTR (SNP) | VAF 178/655 reads (27%) | catalogued as rs757553875; called by muse, mutect2, varscan2
- IGFN1 | c.1242-962C>A | Intron (SNP) | VAF 178/281 reads (63%) | catalogued as rs141855456, COSV55170307; called by muse, mutect2, varscan2
- KLF1 | c.-16T>A | 5'UTR (SNP) | VAF 156/600 reads (26%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818414 C>T | 3'Flank (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- LINC02876 | n.486C>T | RNA (SNP) | VAF 50/263 reads (19%) | catalogued as rs1412812264; called by muse, mutect2, varscan2
- LRRTM3 | c.-27A>C | 5'UTR (SNP) | VAF 43/163 reads (26%) | called by muse, mutect2, varscan2
- MGAT4FP | n.889T>C | RNA (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- MKS1 | c.1408-24G>T | Intron (SNP) | VAF 153/520 reads (29%) | called by muse, mutect2, varscan2
- MLIP | c.64-9905C>T | Intron (SNP) | VAF 60/276 reads (22%) | called by muse, mutect2, varscan2
- MMAB | c.520-143G>T | Intron (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- OPA1 | c.2983+1301A>G | Intron (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- P4HA3 | c.*131G>A | 3'UTR (SNP) | VAF 139/434 reads (32%) | catalogued as rs533764229, COSV59041962; called by muse, mutect2, varscan2
- PARP9 | c.-15C>T | 5'UTR (SNP) | VAF 76/144 reads (53%) | called by muse, mutect2, varscan2
- PCDHB13 | c.*135G>T | 3'UTR (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- PCNX3 | c.3379+111C>T | Intron (SNP) | VAF 103/345 reads (30%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227946 C>A | 3'Flank (SNP) | VAF 92/318 reads (29%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.1640-11C>G | Intron (SNP) | VAF 121/466 reads (26%) | called by muse, mutect2, varscan2
- PSME2 | c.81+26G>A | Intron (SNP) | VAF 103/348 reads (30%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*138C>T | 3'UTR (SNP) | VAF 211/723 reads (29%) | called by muse, mutect2, varscan2
- RAD52 | c.280+21T>G | Intron (SNP) | VAF 79/226 reads (35%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.-12C>T | 5'UTR (SNP) | VAF 44/162 reads (27%) | catalogued as rs377328902; called by mutect2, varscan2
- SEC24B | c.-19C>T | 5'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs773210525; called by muse, mutect2, varscan2
- SLC17A3 | c.304-138G>C | Intron (SNP) | VAF 95/249 reads (38%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088640 G>A | 3'Flank (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- SPECC1L | c.*29G>T | 3'UTR (SNP) | VAF 110/366 reads (30%) | called by muse, mutect2, varscan2
- SYBU | c.-96T>G | 5'UTR (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- TAF15 | c.99+13A>G | Intron (SNP) | VAF 161/560 reads (29%) | called by muse, mutect2, varscan2
- TJAP1 | c.579+285C>T | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, varscan2
- TTN | c.10360+3067G>T | Intron (SNP) | VAF 131/510 reads (26%) | catalogued as COSV100596133; called by muse, mutect2, varscan2
- TTN | c.6791-30dup | Intron (INS) | VAF 35/162 reads (22%) | catalogued as rs762701626; called by mutect2, varscan2
- TTYH3 | c.124-1059A>T | Intron (SNP) | VAF 77/327 reads (24%) | called by muse, mutect2, varscan2
- VAX1 | chr10:117132234 C>T | 3'Flank (SNP) | VAF 154/482 reads (32%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119067927 C>G | 5'Flank (SNP) | VAF 100/438 reads (23%) | catalogued as COSV100333456; called by muse, mutect2, varscan2
- ZNF26 | c.-19C>T | 5'UTR (SNP) | VAF 76/277 reads (27%) | called by muse, mutect2, varscan2
- ZNF727 | c.-106C>A | 5'UTR (SNP) | VAF 144/458 reads (31%) | called by muse, mutect2, varscan2
